Somatic mutation profile of tumor specimen TARGET-30-PAICGF-01A (aliquot TARGET-30-PAICGF-01A-01W) from TARGET case TARGET-30-PAICGF, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Age at diagnosis: 3.5 years (1,278 days).
Specimen TARGET-30-PAICGF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58585032-92c0-4412-96a4-756f27ef8ef0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAICGF-10A (Blood Derived Normal), aliquot TARGET-30-PAICGF-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5e823e6-169f-4738-9fbb-45ee5c8f2971

The open-access MAF lists 18 somatic variants for this specimen: 17 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 15, Silent 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH7 | c.829G>C p.V277L | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV59884077; called by muse, mutect2, varscan2
- FFAR4 | c.1106G>T p.R369I | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV65159922, COSV65160888; called by muse, mutect2, varscan2
- HEPH | c.1225C>T p.P409S (on ENST00000343002; = p.P142S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.041); catalogued as COSV57961624, COSV57968907; called by muse, mutect2, varscan2
- PGLYRP4 | c.641T>G p.V214G | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62836388; called by muse, mutect2
- PLCXD2 | c.337T>G p.F113V | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67339158, COSV67340843; called by muse, mutect2, varscan2
- RELA | c.1533dup p.D512Rfs*21 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | catalogued as rs753829254; called by mutect2, pindel
- STK36 | c.3079T>A p.L1027M | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as COSV55325582; called by muse, mutect2, varscan2
- SUCLG2 | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 71/421 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV56204214; called by muse, mutect2, varscan2
- ABCB11 | c.1924G>C p.E642Q | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.282); called by muse, mutect2
- AFTPH | c.1735del p.Q579Kfs*71 | Frame Shift Del (DEL) | VAF 37/281 reads (13%) | called by mutect2, pindel, varscan2
- AVL9 | c.1597G>T p.G533W | Missense Mutation (SNP) | VAF 12/367 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BMP7 | c.1151A>G p.H384R | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BMP7 | c.1150C>A p.H384N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GABRG3 | c.1072C>A p.P358T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSMD6 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 25/968 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMC7 | c.611T>G p.I204S | Missense Mutation (SNP) | VAF 5/126 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- ZNF549 | c.716G>T p.R239I (on ENST00000376233 / NM_001199295.2; = p.R226I on NM_153263.2) | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); called by muse, mutect2
- C1orf158 | c.267C>A p.P89= | Silent (SNP) | VAF 71/527 reads (13%) | catalogued as COSV55346459; called by muse, mutect2, varscan2
